Gene-level copy-number profile of tumor specimen TCGA-A5-A0G3-01A from TCGA case TCGA-A5-A0G3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 61.4 years (22,421 days).
Specimen TCGA-A5-A0G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.9a5539d4-bd00-4a7f-9fa1-b17adf7d20a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A0G3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate.
https://portal.gdc.cancer.gov/files/68a14abd-8d57-4a9f-9993-80203bbebd2e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 104; copy number 2: 5,860; copy number 3: 18,821; copy number 4: 15,092; copy number 5: 13,950; copy number 6: 957; copy number 7: 2,804; copy number 8: 271; copy number 9: 223; copy number 10: 403; copy number 11: 249; copy number 12: 89; copy number 13: 37; copy number 14: 550; copy number 15: 59; copy number 16: 42; copy number 17: 92; copy number 18: 57; copy number 19: 61; copy number 26: 94.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene (within-gene range 0–3): AC010983.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,850 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7 (broad region; genes not listed).
- chr2:25,697,076–26,456,711, 23 genes, copy number 7 (within-gene range 5–7): Y_RNA, ASXL2, TPM3P7, PTGES3P2, AC064847.1, NDUFB4P4, KIF3C, UQCRHP2, TRMT112P6, RAB10, RNU6-942P, RPS2P15, EMP2P1, SMARCE1P6, AC011742.1, PPIL1P1, GAREM2, HADHA, HADHB, AC010896.1, ADGRF3, SELENOI, DRC1.
- chr5:38,682,070–39,572,639, 14 genes, copy number 7: AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1.
- chr6:167,607–6,654,983, 137 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:23,298,739–24,795,496, 30 genes, copy number 9–26 (within-gene range 3–26): MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1.
- chr7:31,751,179–57,837,046, 517 genes, copy number 10–17 (within-gene range 4–17) (broad region; genes not listed).
- chr8:55,067,585–56,917,190, 36 genes, copy number 9–14: AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P.
- chr8:86,553,977–88,887,573, 19 genes, copy number 12 (within-gene range 4–12): CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1.
- chr8:89,826,593–93,166,850, 46 genes, copy number 8: AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87.
- chr8:93,215,925–93,298,528, 3 genes, copy number 8: AC016885.1, AC016885.3, AC016885.2.
- chr8:115,950,511–139,127,953, 295 genes, copy number 7–26 (within-gene range 3–26) (broad region; genes not listed).
- chr12:40,393,395–48,146,404, 137 genes, copy number 11–18 (within-gene range 3–18) (broad region; genes not listed).
- chr16:11,359,845–11,976,643, 21 genes, copy number 17 (within-gene range 4–17): AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr16:11,976,851–12,095,307, 4 genes, copy number 17: AC007216.1, RPS23P6, AC007601.1, AC007601.2.
- chr18:47,390–26,657,401, 492 genes, copy number 8–18 (broad region; genes not listed).
- chr18:26,685,954–26,865,771, 6 genes, copy number 18: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4.
- chr19:27,638,483–39,846,379, 455 genes, copy number 8–19 (within-gene range 3–19) (broad region; genes not listed).
- chr20:37,602,852–38,166,578, 11 genes, copy number 7: GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2.

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
